Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A3A6, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A3A6-01A (Primary Tumor).

Patient Key:

Surgical date:

TISSUE DESCRIPTION:

Right lobe liver (645 grams, 17 x 12 x 7 cm), gallbladder (9 x 3 x 2 cm) and separately submitted pericholedochal lymph node (3 cm) A1, B1, C1, C2, C3, C4, C5, C6, C7, C8

DIAGNOSIS:

Right lobe liver, resection: Grade 2 hepatocellular carcinoma is identified forming a well-circumscribed mass (8 x 6 x 6 cm) in the right lobe of the liver. The closest surgical resection margin is at a distance of 2 mm. The margins of resection are free of involvement.

Gallbladder, excision: Mild chronic cholecystitis.

Pericholedochal lymph node, excision: Single inflammatory lymph node identified. Paraffin section immunostains show neoplastic cells are positive for CAM 5.2, vimentin, and alpha fetoprotein, while they are negative for p-CEA, S-100, and actin. In situ hybridization for albumin mRNA is weakly positive. These results support the diagnosis of hepatoma. HMB-45 immunostain, however, is also positive in neoplastic cells; the meaning of this staining reactivity is unclear.

Note: Seen with Dr. and Dr.

PRELIMINARY FROZEN SECTION CONSULTATION:

Hold to confirm - grade 3 hepatocellular carcinoma right lobe liver.

ICD . 0 . 3
carcinoma, hepatocellular, . 0 0 5 8170/3
Site: liver C22.0
fw
9/22/11

Qual/Sync/Chonous Primary Noted		

Source: NCI Genomic Data Commons file bc748661-c0b6-47e9-bc63-57d6ba36ea81 (TCGA-DD-A3A6.EEA9EFFB-B5F9-42D9-B452-E165E018C33C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).